Gene-level copy-number profile of tumor specimen TCGA-KK-A8ID-01A from TCGA case TCGA-KK-A8ID, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.8 years (25,851 days).
Specimen TCGA-KK-A8ID-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.170808e1-c21e-49f2-81ba-f25946b53768.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A8ID-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b11fe10-fa81-4ead-a18b-8a8041acb106

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,688; copy number 2: 40,922; copy number 3: 12,555; copy number 4: 2,536; copy number 5: 837; copy number 6: 168; copy number 7: 45; copy number 8: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A8ID-01A-11D-A363-01): tumor purity 0.66, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,093 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:190,478,551–190,494,297, 2 genes, copy number 5: LINC01351, AL391645.1.
- chr2:178,828,349–179,050,086, 2 genes, copy number 5 (within-gene range 3–5): AC092640.1, CCDC141.
- chr2:179,001,756–180,007,297, 10 genes, copy number 5: RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22.
- chr2:195,994,259–197,786,762, 36 genes, copy number 5: E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P, AC068544.2, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL.
- chr2:241,356,285–241,637,158, 10 genes, copy number 5: FARP2, AC005104.2, MIR3133, KCTD5P1, STK25, BOK-AS1, BOK, AC133528.1, THAP4, RNA5SP122.
- chr4:15,864,938–16,898,678, 15 genes, copy number 5: HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1, LDB2, AC104656.1.
- chr4:111,551,854–112,546,881, 20 genes, copy number 5–6: AC083795.1, AC083795.2, AC139718.2, AC139718.1, AC004704.1, CCDC34P1, TUBB8P3, AC093663.1, FAM241A, AC093663.2, AC109347.1, AP1AR, AC109347.2, TIFA, ALPK1, RTEL1P1, TOX4P1, NEUROG2, NEUROG2-AS1, RPL23AP94.
- chr4:157,568,731–159,401,246, 40 genes, copy number 5–6: AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2.
- chr4:161,378,953–165,762,778, 61 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr4:168,828,919–170,605,450, 29 genes, copy number 5–7: AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1, HSP90AA6P.
- chr5:144,856,890–146,617,004, 26 genes, copy number 5–6 (within-gene range 3–6): AC132803.1, NAMPTP2, ASS1P10, AC137770.1, AC008700.1, PRELID2, AC011411.1, GRXCR2, SH3RF2, AC005351.1, PLAC8L1, AC091887.1, LARS1, RPL35AP16, RPL35AP17, AC091959.1, RBM27, RNU7-180P, AC011396.2, POU4F3, AC011396.3, AC011396.1, TCERG1, AC011375.1, GPR151, AC008728.1.
- chr5:146,586,099–146,707,600, 3 genes, copy number 6: RNA5SP196, RN7SL791P, KRT8P48.
- chr5:167,937,717–172,454,525, 69 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:108,848,416–109,094,819, 7 genes, copy number 8: ARMC2, AL445189.1, ATP5MFP2, ARMC2-AS1, SESN1, AL390208.1, RNU6-653P.
- chr6:110,341,973–111,483,715, 30 genes, copy number 6 (within-gene range 3–6): AL050350.1, DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1, SLC16A10, RNU6-960P, AL360227.1, MFSD4B, AL080317.1, REV3L, AL080317.2, FCF1P5, REV3L-IT1.
- chr6:113,357,003–115,358,752, 22 genes, copy number 5: AL589684.1, LINC02518, AL513123.1, RPS27AP11, LINC02541, FO393415.2, FO393415.1, MARCKS, MROCKI, LINC02880, HDAC2, HDAC2-AS2, NUDT19P3, HS3ST5, RPSAP43, RNA5SP213, DNAJA1P4, AL138830.2, AL138830.1, AL590550.1, RNU6-475P, AL606845.1.
- chr7:3,083,252–4,269,000, 7 genes, copy number 6 (within-gene range 3–6): AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1.
- chr7:53,559,214–53,811,952, 5 genes, copy number 5 (within-gene range 2–5): AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1.
- chr8:38,699,274–39,580,134, 17 genes, copy number 6: AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr8:96,126,967–101,669,726, 123 genes, copy number 5 (broad region; genes not listed).
- chr8:101,686,547–101,872,549, 3 genes, copy number 5: AP000426.1, AP001329.1, PDCL3P2.
- chr9:12,098,660–12,300,451, 3 genes, copy number 5 (within-gene range 3–5): AL589678.1, JKAMPP1, RNU2-47P.
- chr10:98,134,624–99,732,112, 24 genes, copy number 5 (within-gene range 3–5): R3HCC1L, LOXL4, AL139241.1, PYROXD2, MIR1287, HPS1, MIR4685, AL139243.1, HPSE2, MIR6507, ARL5AP2, RPL7P36, CNNM1, GOT1, AL391684.1, LINC01475, AL513542.1, NKX2-3, SLC25A28, AL353719.1, AL133353.1, AL133353.2, ENTPD7, EBAG9P1.
- chr11:84,545,131–85,021,655, 8 genes, copy number 5: HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6.
- chr11:105,609,994–108,467,531, 42 genes, copy number 5–6 (within-gene range 3–6): GRIA4, HSPD1P13, RNU4-55P, RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65.
- chr12:41,658,676–41,700,251, 3 genes, copy number 5: RNA5SP360, MTND2P17, MTND1P24.
- chr12:77,129,178–77,317,234, 2 genes, copy number 5 (within-gene range 3–5): AC079030.1, LINC02464.
- chr12:109,116,595–110,218,793, 29 genes, copy number 5 (within-gene range 3–5): ACACB, FOXN4, MYO1H, LINC01486, AC007570.1, KCTD10, UBE3B, MMAB, RNU4-32P, MVK, RN7SKP250, FAM222A, FAM222A-AS1, TRPV4, MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1, TCHP, GIT2, AC084876.1, AC084876.2, ANKRD13A, C12orf76, AC007546.1, AC007546.3, AC007546.2, IFT81.
- chr13:19,172,773–21,604,181, 77 genes, copy number 5–8 (broad region; genes not listed).
- chr13:30,103,178–30,996,138, 28 genes, copy number 5 (within-gene range 3–5): LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066.
- chr14:37,827,798–38,606,098, 9 genes, copy number 5: RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1.
- chr14:39,230,231–40,905,513, 8 genes, copy number 5 (within-gene range 2–5): MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1, AL049828.2, AL390800.1.
- chr15:23,562,062–23,687,305, 5 genes, copy number 5: MIR4508, MKRN3, AC126407.1, MAGEL2, NDN.
- chr16:49,277,917–49,469,875, 7 genes, copy number 5: CBLN1, AC007614.1, AC007614.2, C16orf78, AC007861.1, AC007861.2, LINC02179.
- chr17:19,020,656–21,092,351, 132 genes, copy number 5 (broad region; genes not listed).
- chr18:58,371,566–58,986,480, 25 genes, copy number 5–7 (within-gene range 3–7): AC090236.2, AC090236.1, AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P.
- chr19:6,199,405–6,393,981, 13 genes, copy number 5: AC011471.4, MLLT1, AC011471.2, AC011471.3, ACER1, AC011491.3, CLPP, ALKBH7, PSPN, GTF2F1, AC011491.2, MIR6885, MIR6790.
- chr19:27,638,483–29,213,151, 36 genes, copy number 5 (within-gene range 3–5): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1.
- chr19:53,682,159–54,155,681, 73 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:36,233,851–37,241,619, 25 genes, copy number 5 (within-gene range 3–5): AL121895.2, AAR2, DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1, RBL1, RPS3AP3, RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2.

Autosomal genes at a single copy (total copy number 1): 482. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
